Somatic mutation profile of tumor specimen TARGET-40-NAAEDH-06A (aliquot TARGET-40-NAAEDH-06A-01D) from TARGET case TARGET-40-NAAEDH, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 17.8 years (6,492 days).
Specimen TARGET-40-NAAEDH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9010faf6-7431-4d6f-ae7e-d85c5e4cb2a9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAEDH-10A (Blood Derived Normal), aliquot TARGET-40-NAAEDH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2de713cf-a4fd-4f28-ae11-b42df840298c

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, Nonsense Mutation 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD1 | c.8423G>T p.R2808L (on ENST00000520002; = p.R2807L on NM_033225.6) | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs774812490, COSV59359077; called by muse, mutect2, varscan2
- DNAH9 | c.781G>C p.D261H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV52355426, COSV52378439; called by muse, varscan2
- CLCN5 | c.1003C>A p.L335M | Missense Mutation (SNP) | VAF 73/83 reads (88%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- FAM171A1 | c.1371C>G p.Y457* | Nonsense Mutation (SNP) | VAF 44/155 reads (28%) | called by muse, mutect2, varscan2
- LAMA1 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- LTBP2 | c.931T>C p.S311P | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TDRD1 | c.2890+1G>C p.X964_splice | Splice Site (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- VPS29 | c.356T>A p.F119Y | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ALMS1 | c.2160G>A p.E720= | Silent (SNP) | VAF 27/123 reads (22%) | called by muse, mutect2
- ABCC9 | chr12:21801091 C>G | 3'Flank (SNP) | VAF 19/102 reads (19%) | called by muse, mutect2, varscan2
